MMRF case MMRF_1078 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/53ee9800-3efc-4b5e-b9d4-d6c440c17494

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 45 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 45.7 years (16,699 days); ISS stage: I; Days to last known disease status: 1,783 days (4.9 years); Days to last follow up: 1,783 days (4.9 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 74 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 75 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 77 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 174 days; Days to treatment end: 174 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 177 days; Days to treatment end: 177 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -13 (ECOG 0): M Protein 4.27 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 88 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.09 mg/dL; Immunoglobulin G 49.4 g/L; Immunoglobulin A 0.22 g/L; Immunoglobulin M 0.06 g/L; Beta 2 Microglobulin 2.51 µg/mL; Lactate Dehydrogenase 3.08 µkat/L; Hemoglobin 8.06 mmol/L; Leukocytes 5 ×10⁹/L; Absolute Neutrophil 2.15 ×10⁹/L; Platelets 222 ×10⁹/L; Creatinine 76 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.15 mmol/L; Albumin 38 g/L; Total Protein 11 g/dL; Glucose 5.17 mmol/L.
- Day 64 (ECOG 0): M Protein 0.17 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.92 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.7 mg/dL; Immunoglobulin G 5.08 g/L; Immunoglobulin A 0.3 g/L; Immunoglobulin M 0.42 g/L; Hemoglobin 8.56 mmol/L; Leukocytes 5.8 ×10⁹/L; Absolute Neutrophil 4.41 ×10⁹/L; Platelets 175 ×10⁹/L; Creatinine 84 µmol/L; Blood Urea Nitrogen 8.21 mmol/L; Calcium 2.33 mmol/L; Albumin 40 g/L; Total Protein 6.6 g/dL; Glucose 6.11 mmol/L.
- Day 169 (ECOG 0): M Protein 0.08 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.04 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.81 mg/dL; Hemoglobin 8.31 mmol/L; Leukocytes 4.2 ×10⁹/L; Absolute Neutrophil 1.99 ×10⁹/L; Platelets 321 ×10⁹/L; Creatinine 82.2 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.3 mmol/L; Albumin 42 g/L; Total Protein 6.7 g/dL; Glucose 4.57 mmol/L.
- Day 246 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.13 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.57 mg/dL; Immunoglobulin G 8.03 g/L; Immunoglobulin A 2.54 g/L; Immunoglobulin M 0.49 g/L; Hemoglobin 7.69 mmol/L; Leukocytes 5.4 ×10⁹/L; Absolute Neutrophil 2.17 ×10⁹/L; Platelets 165 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.25 mmol/L; Albumin 40 g/L; Total Protein 6.5 g/dL; Glucose 4.73 mmol/L.
- Day 344 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.68 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.25 mg/dL; Immunoglobulin G 7.96 g/L; Immunoglobulin A 1.9 g/L; Immunoglobulin M 0.33 g/L; Hemoglobin 8.8 mmol/L; Leukocytes 5.8 ×10⁹/L; Absolute Neutrophil 3.02 ×10⁹/L; Platelets 187 ×10⁹/L; Creatinine 90.2 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.38 mmol/L; Albumin 42 g/L; Total Protein 6.9 g/dL; Glucose 4.84 mmol/L.
- Day 442 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.48 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.13 mg/dL; Immunoglobulin G 14.8 g/L; Hemoglobin 8.68 mmol/L; Leukocytes 5.4 ×10⁹/L; Absolute Neutrophil 2.62 ×10⁹/L; Platelets 191 ×10⁹/L; Creatinine 73.4 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.33 mmol/L; Albumin 44 g/L; Total Protein 7.1 g/dL; Glucose 5.5 mmol/L.
- Day 540 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.12 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.09 mg/dL; Hemoglobin 8.43 mmol/L; Leukocytes 5 ×10⁹/L; Absolute Neutrophil 2.11 ×10⁹/L; Platelets 166 ×10⁹/L; Creatinine 69.8 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.23 mmol/L; Albumin 41 g/L; Total Protein 6.8 g/dL; Glucose 3.69 mmol/L.
- Day 596 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.3 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.29 mg/dL; Hemoglobin 8.62 mmol/L; Leukocytes 6.5 ×10⁹/L; Absolute Neutrophil 3.28 ×10⁹/L; Platelets 171 ×10⁹/L; Creatinine 78.7 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.2 mmol/L; Albumin 41 g/L; Total Protein 7 g/dL; Glucose 4.62 mmol/L.
- Day 701 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 1.22 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.41 mg/dL; Immunoglobulin G 0.52 g/L; Immunoglobulin A 1.99 g/L; Immunoglobulin M 10.5 g/L; Hemoglobin 8.87 mmol/L; Leukocytes 5.1 ×10⁹/L; Absolute Neutrophil 2.37 ×10⁹/L; Platelets 178 ×10⁹/L; Creatinine 81.3 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.33 mmol/L; Albumin 43 g/L; Total Protein 7 g/dL; Glucose 4.79 mmol/L.
- Day 792 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.18 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.28 mg/dL; Immunoglobulin G 11.6 g/L; Immunoglobulin A 2.44 g/L; Immunoglobulin M 0.73 g/L; Hemoglobin 9.3 mmol/L; Leukocytes 5.9 ×10⁹/L; Absolute Neutrophil 3.57 ×10⁹/L; Platelets 204 ×10⁹/L; Creatinine 74.3 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.4 mmol/L; Albumin 43.6 g/L; Total Protein 7.5 g/dL; Glucose 5.61 mmol/L.
- Day 911 (ECOG 0): M Protein 0 g/dL; Hemoglobin 8.93 mmol/L; Leukocytes 5.5 ×10⁹/L; Absolute Neutrophil 2.76 ×10⁹/L; Platelets 158 ×10⁹/L; Creatinine 84 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.3 mmol/L; Albumin 41 g/L; Total Protein 7 g/dL; Glucose 5.67 mmol/L.
- Day 1,034 (ECOG 1): M Protein 0 g/dL; Immunoglobulin G 11 g/L; Immunoglobulin A 2.29 g/L; Immunoglobulin M 0.78 g/L; Hemoglobin 8.99 mmol/L; Leukocytes 5.8 ×10⁹/L; Absolute Neutrophil 2.54 ×10⁹/L; Platelets 191 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.25 mmol/L; Albumin 41 g/L; Total Protein 7.2 g/dL; Glucose 4.35 mmol/L.
- Day 1,163: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.48 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.46 mg/dL; Immunoglobulin G 11 g/L; Immunoglobulin A 2.53 g/L; Immunoglobulin M 0.8 g/L; Hemoglobin 8.99 mmol/L; Leukocytes 5.3 ×10⁹/L; Absolute Neutrophil 2.73 ×10⁹/L; Platelets 205 ×10⁹/L; Creatinine 82.2 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.23 mmol/L; Albumin 41 g/L; Total Protein 7.4 g/dL; Glucose 5.61 mmol/L.
- Day 1,289: Hemoglobin 7.07 mmol/L; Leukocytes 12.1 ×10⁹/L; Absolute Neutrophil 10.4 ×10⁹/L; Platelets 154 ×10⁹/L; Creatinine 69 µmol/L; Blood Urea Nitrogen 3.21 mmol/L; Calcium 1.95 mmol/L; Glucose 8.36 mmol/L.
- Day 1,399: Hemoglobin 7.44 mmol/L; Leukocytes 9.8 ×10⁹/L; Absolute Neutrophil 7.65 ×10⁹/L; Platelets 181 ×10⁹/L.
- Day 1,510: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.82 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.34 mg/dL; Immunoglobulin G 11.5 g/L; Immunoglobulin A 2.59 g/L; Immunoglobulin M 0.85 g/L; Hemoglobin 8.43 mmol/L; Leukocytes 6.4 ×10⁹/L; Absolute Neutrophil 3.39 ×10⁹/L; Platelets 206 ×10⁹/L.
- Day 1,660: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.67 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.23 mg/dL; Immunoglobulin G 11.5 g/L; Immunoglobulin A 2.59 g/L; Immunoglobulin M 0.94 g/L; Hemoglobin 9.05 mmol/L; Leukocytes 5.8 ×10⁹/L; Absolute Neutrophil 2.65 ×10⁹/L; Platelets 198 ×10⁹/L; Creatinine 86.6 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.23 mmol/L; Albumin 42 g/L; Total Protein 7.1 g/dL; Glucose 6.82 mmol/L.
- Day 1,783: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.88 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.18 mg/dL; Immunoglobulin G 10.7 g/L; Immunoglobulin A 2.36 g/L; Immunoglobulin M 0.85 g/L; Hemoglobin 9.3 mmol/L; Leukocytes 6.6 ×10⁹/L; Absolute Neutrophil 3.21 ×10⁹/L; Platelets 211 ×10⁹/L; Creatinine 86.6 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.25 mmol/L; Albumin 40 g/L; Total Protein 7 g/dL; Glucose 5.94 mmol/L.

Other clinical attributes
- Day -13: Weight: 103 kg; Height: 179 cm.

Family history
- Relative with cancer history: yes; Relationship type: Father; Relationship primary diagnosis: Bladder Cancer; Relationship sex at birth: male.
- Relative with cancer history: yes; Relationship type: Father; Relationship primary diagnosis: Lung Cancer; Relationship sex at birth: male.

Biospecimens (2 samples)
- Sample MMRF_1078_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -13 days.
- Sample MMRF_1078_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -13 days.
